Somatic mutation profile of tumor specimen 0E1BO3 from CCDI case PBCVUD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1BO3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6de79b0d-7461-46c7-8235-589e98390237.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1BOD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eaa019fd-9b6c-4935-8cd5-0a9017187c0e

The open-access MAF lists 29 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 8, Nonsense Mutation 2, In Frame Del 2, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYLD | c.1112C>A p.S371* | Nonsense Mutation (SNP) | VAF 206/249 reads (83%) | catalogued as rs886040872, CM001113, COSV61094720; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH11 | c.2966G>A p.R989Q | Missense Mutation (SNP) | VAF 94/785 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1178187217, COSV100176009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BCORL1 | c.1093G>A p.G365S | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.211); catalogued as rs1299443580; called by muse, mutect2, varscan2
- CEACAM20 | c.113C>A p.P38Q | Missense Mutation (SNP) | VAF 80/505 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as COSV57603839; called by muse, mutect2, varscan2
- CNTNAP1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 21/683 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52853172, COSV52853898; called by muse, mutect2
- LOXHD1 | c.1717G>A p.V573I | Missense Mutation (SNP) | VAF 111/511 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); catalogued as rs188554662, COSV59661682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LSP1 | c.706C>A p.Q236K | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100289214; called by muse, mutect2, varscan2
- SDE2 | c.806C>A p.A269E | Missense Mutation (SNP) | VAF 64/864 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV55250614; called by muse, mutect2
- SRGAP1 | c.2471C>T p.T824M | Missense Mutation (SNP) | VAF 259/578 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.513); catalogued as rs780416426; called by muse, mutect2, varscan2
- TSPAN7 | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 250/405 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1804492, CM156727; called by muse, mutect2, varscan2
- CARNS1 | c.34_36del p.K12del | In Frame Del (DEL) | VAF 122/600 reads (20%) | called by mutect2, pindel, varscan2
- CD101 | c.2086G>T p.E696* | Nonsense Mutation (SNP) | VAF 55/392 reads (14%) | called by muse, mutect2, varscan2
- DENND5B | c.2399C>T p.S800L | Missense Mutation (SNP) | VAF 93/266 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMPD3 | c.2786C>A p.P929Q | Missense Mutation (SNP) | VAF 96/342 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 30/759 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- PRR7 | c.225_236del p.Q76_P79del | In Frame Del (DEL) | VAF 72/192 reads (38%) | called by mutect2, pindel, varscan2
- SLC35C2 | c.866A>C p.H289P | Missense Mutation (SNP) | VAF 337/774 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ZNF585B | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- ATXN3 | c.625C>T p.L209= | Silent (SNP) | VAF 135/443 reads (30%) | called by muse, mutect2, varscan2
- DACT1 | c.1401C>T p.S467= | Silent (SNP) | VAF 107/386 reads (28%) | catalogued as rs781652020; called by muse, mutect2, varscan2
- DTX4 | c.1551G>A p.P517= | Silent (SNP) | VAF 18/565 reads (3%) | catalogued as rs1019485414, COSV57091964; called by muse, mutect2
- MX1 | c.1824C>T p.Y608= | Silent (SNP) | VAF 132/445 reads (30%) | catalogued as rs764441180; called by muse, mutect2, varscan2
- NRROS | c.927C>T p.N309= | Silent (SNP) | VAF 100/269 reads (37%) | catalogued as rs756226162; called by muse, mutect2, varscan2
- TET1 | c.3648G>A p.S1216= | Silent (SNP) | VAF 34/548 reads (6%) | catalogued as rs144122659, COSV101018360; called by muse, mutect2
- TRIP10 | c.177C>T p.A59= | Silent (SNP) | VAF 154/436 reads (35%) | catalogued as COSV99901348; called by muse, mutect2, varscan2
- ZNF165 | c.1173G>T p.R391= | Silent (SNP) | VAF 18/656 reads (3%) | called by muse, mutect2
- GYG2 | c.*4G>A | 3'UTR (SNP) | VAF 61/321 reads (19%) | catalogued as rs766537885; called by muse, mutect2, varscan2
- MBP | c.751-37G>T | Intron (SNP) | VAF 138/344 reads (40%) | called by muse, mutect2, varscan2
- SLC35A2 | c.91+36G>A | Intron (SNP) | VAF 38/179 reads (21%) | called by muse, mutect2, varscan2
